Somatic mutation profile of tumor specimen C3L-00098-02 (aliquot CPT0000980005) from CPTAC case C3L-00098, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 63.5 years (23,197 days).
Specimen C3L-00098-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09a1066a-853f-4173-bc5f-df522ecb6a81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00098-31 (Blood Derived Normal), aliquot CPT0003930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49b497df-c090-4c91-a11c-0dd42fb3f3ff

The open-access MAF lists 86 somatic variants for this specimen: 57 protein-altering or splice-affecting, 18 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 18, Intron 5, Nonsense Mutation 4, 3'UTR 3, 3'Flank 2, Frame Shift Ins 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 125/210 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 95/210 reads (45%) | catalogued as COSV52455835; called by muse, mutect2, varscan2
- ARHGEF3 | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as COSV56325740; called by muse, mutect2, varscan2
- ARID2 | c.928C>G p.R310G | Missense Mutation (SNP) | VAF 79/131 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57600152; called by muse, mutect2, varscan2
- ASIC4 | c.1367G>A p.R456Q (on ENST00000347842 / NM_182847.3; = p.R475Q on NM_018674.6) | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs753563170; called by muse, mutect2, varscan2
- BHLHE22 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.078); catalogued as rs557592166, COSV100418053; called by muse, varscan2
- CELSR1 | c.4450C>T p.R1484C | Missense Mutation (SNP) | VAF 100/287 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53099246; called by muse, mutect2, varscan2
- CFAP47 | c.4439A>T p.E1480V | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.166); catalogued as COSV100544856; called by muse, mutect2, varscan2
- CFAP47 | c.5512A>G p.I1838V | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.503); catalogued as rs747470042; called by muse, mutect2, varscan2
- CFAP57 | c.2737C>T p.R913* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as rs190140571, COSV65264795; called by muse, mutect2, varscan2
- DISP3 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs771271771, COSV53832144; called by muse, mutect2, varscan2
- DMRTC2 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.142); catalogued as rs782633246; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1655C>T p.T552M | Missense Mutation (SNP) | VAF 57/341 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200653424; called by muse, mutect2, varscan2
- FAM177A1 | c.313C>T p.R105W (on ENST00000382406 / NM_001289022.2; = p.R128W on NM_173607.5) | Missense Mutation (SNP) | VAF 62/292 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777218565, COSV99805791; called by muse, mutect2, varscan2
- FAM205A | c.2357C>A p.S786* | Nonsense Mutation (SNP) | VAF 200/758 reads (26%) | catalogued as COSV101113037; called by muse, mutect2, varscan2
- FRAS1 | c.6010G>A p.G2004S | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771251344; called by muse, mutect2, varscan2
- GPR4 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1472156703, COSV59916854; called by muse, mutect2, varscan2
- KLK2 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as rs572630957, COSV57571211; called by muse, mutect2, varscan2
- LRIT2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as rs979282940; called by muse, mutect2, varscan2
- MAS1L | c.820C>A p.L274I | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1236370834; called by muse, mutect2, varscan2
- NSD2 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 171/460 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs757593548; called by muse, mutect2, varscan2
- OSMR | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 62/285 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.644); catalogued as rs769344392, COSV57085792; called by muse, varscan2
- PCDHA13 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); catalogued as COSV56525028; called by muse, mutect2, varscan2
- PLA2G4A | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.794); catalogued as rs1360297970, COSV66556457; called by muse, mutect2, varscan2
- PM20D1 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs572366251, COSV65649294; called by muse, mutect2, varscan2
- PNRC1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 176/415 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.736); catalogued as COSV100260066, COSV60139463; called by muse, mutect2, varscan2
- QARS1 | c.1845G>C p.E615D | Missense Mutation (SNP) | VAF 78/279 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as rs571159624; called by muse, mutect2, varscan2
- SGSH | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 142/300 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs937752107, COSV58339129; called by muse, mutect2, varscan2
- SRGAP3 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.558); catalogued as rs1466953648; called by muse, mutect2, varscan2
- TMEM94 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 105/447 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs753606974, COSV58595669; called by muse, mutect2, varscan2
- TOP1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as COSV100793824; called by muse, mutect2, varscan2
- VPS52 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 100/250 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs767659940, COSV71403638; called by muse, mutect2, varscan2
- WDR97 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1163779423; called by muse, mutect2, varscan2
- WDSUB1 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1274167227; called by muse, mutect2, varscan2
- XIRP1 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs760098747, COSV61140086; called by muse, mutect2, varscan2
- ZFP57 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 101/442 reads (23%) | catalogued as rs1446826654, CD154903; called by muse, mutect2, varscan2
- ANP32D | c.89A>C p.N30T | Missense Mutation (SNP) | VAF 94/141 reads (67%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf99 | c.168T>A p.H56Q | Missense Mutation (SNP) | VAF 114/304 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- CACNG1 | c.160T>C p.W54R | Missense Mutation (SNP) | VAF 294/571 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD14 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CDC42EP5 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL6A3 | c.8708C>T p.P2903L | Missense Mutation (SNP) | VAF 151/292 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CUL5 | c.1547del p.N516Ifs*13 | Frame Shift Del (DEL) | VAF 57/109 reads (52%) | called by mutect2, pindel, varscan2
- GABPA | c.446C>G p.T149R | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GMNC | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ICAM5 | c.1843A>T p.T615S | Missense Mutation (SNP) | VAF 69/111 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM7A | c.1177C>G p.L393V | Missense Mutation (SNP) | VAF 71/104 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- L3MBTL4 | c.1756G>A p.V586M | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LPP | c.63_64dup p.R22Hfs*28 | Frame Shift Ins (INS) | VAF 137/312 reads (44%) | called by mutect2, pindel, varscan2
- MYO5B | c.5462dup p.L1821Ffs*5 | Frame Shift Ins (INS) | VAF 87/484 reads (18%) | called by mutect2, pindel, varscan2
- NUBPL | c.669G>C p.E223D | Missense Mutation (SNP) | VAF 127/379 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- PPP1R21 | c.181A>C p.S61R | Missense Mutation (SNP) | VAF 109/295 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRR3 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, varscan2
- TNK1 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 121/160 reads (76%) | SIFT tolerated (0.32); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ZNF365 | c.98A>T p.D33V | Missense Mutation (SNP) | VAF 156/457 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF462 | c.4202del p.S1401* | Frame Shift Del (DEL) | VAF 81/142 reads (57%) | called by mutect2, pindel*, varscan2
- ZNF7 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 89/514 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ADAMTSL3 | c.843C>T p.H281= | Silent (SNP) | VAF 119/163 reads (73%) | catalogued as rs1441422216, COSV54466577; called by muse, mutect2, varscan2
- CALHM5 | c.654T>C p.Y218= | Silent (SNP) | VAF 83/195 reads (43%) | catalogued as rs773523537; called by muse, mutect2, varscan2
- DAAM1 | c.2550C>A p.I850= | Silent (SNP) | VAF 63/211 reads (30%) | catalogued as COSV100658558; called by muse, mutect2, varscan2
- DPYS | c.405G>C p.V135= | Silent (SNP) | VAF 205/547 reads (37%) | catalogued as COSV60914404; called by muse, mutect2, varscan2
- KCTD8 | c.529C>T p.L177= | Silent (SNP) | VAF 91/228 reads (40%) | called by muse, mutect2, varscan2
- KIRREL1 | c.114C>G p.A38= | Silent (SNP) | VAF 94/273 reads (34%) | called by muse, mutect2, varscan2
- MAST1 | c.1764C>T p.F588= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs1018835734, COSV52255526; called by muse, mutect2, varscan2
- MMP16 | c.336A>G p.K112= | Silent (SNP) | VAF 82/231 reads (35%) | called by muse, mutect2, varscan2
- PGR | c.1626C>G p.L542= | Silent (SNP) | VAF 58/79 reads (73%) | catalogued as rs781712664; called by muse, mutect2, varscan2
- PGR | c.768C>G p.V256= | Silent (SNP) | VAF 96/160 reads (60%) | called by muse, mutect2, varscan2
- PITX3 | c.672G>T p.G224= | Silent (SNP) | VAF 33/84 reads (39%) | called by muse, mutect2, varscan2
- PKD1 | c.12693G>A p.Q4231= (on ENST00000262304 / NM_001009944.3; = p.Q4230= on NM_000296.4) | Silent (SNP) | VAF 102/304 reads (34%) | catalogued as rs770831279; called by muse, mutect2, varscan2
- SH2D5 | c.1179G>A p.E393= (on ENST00000444387 / NM_001103161.2; = p.E309= on NM_001103160.2) | Silent (SNP) | VAF 69/136 reads (51%) | catalogued as COSV56120765; called by muse, mutect2, varscan2
- STEAP2 | c.633C>T p.L211= | Silent (SNP) | VAF 27/69 reads (39%) | called by muse, varscan2
- TRIM36 | c.81C>T p.I27= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as rs763230187, COSV56693372; called by muse, mutect2, varscan2
- TRIM60 | c.81G>T p.V27= | Silent (SNP) | VAF 31/117 reads (26%) | called by muse, mutect2, varscan2
- TRIM65 | c.1107G>A p.E369= | Silent (SNP) | VAF 109/472 reads (23%) | called by muse, mutect2, varscan2
- YOD1 | c.135G>A p.T45= | Silent (SNP) | VAF 57/185 reads (31%) | called by muse, mutect2, varscan2
- AC068631.2 | chr3:186597147 C>T | 3'Flank (SNP) | VAF 288/598 reads (48%) | catalogued as rs1480238733; called by muse, mutect2, varscan2
- C2orf91 | n.523G>T | RNA (SNP) | VAF 15/112 reads (13%) | catalogued as rs1439246786; called by muse, mutect2, varscan2
- EZH2 | c.247-4174C>T | Intron (SNP) | VAF 27/154 reads (18%) | called by muse, mutect2, varscan2
- GFOD1 | c.*3860C>G | 3'UTR (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- GGNBP1 | chr6:33593252 G>C | 3'Flank (SNP) | VAF 66/159 reads (42%) | called by muse, mutect2, varscan2
- RIMS2 | c.2083+50C>T | Intron (SNP) | VAF 44/124 reads (35%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*1999T>C | 3'UTR (SNP) | VAF 15/62 reads (24%) | catalogued as rs905482451; called by muse, mutect2, varscan2
- TGM5 | c.1106-40G>T | Intron (SNP) | VAF 191/305 reads (63%) | called by muse, mutect2, varscan2
- TINF2 | c.*25C>T | 3'UTR (SNP) | VAF 69/299 reads (23%) | called by muse, mutect2, varscan2
- UBA1 | c.1576-495G>T | Intron (SNP) | VAF 75/183 reads (41%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4193A>T | Intron (SNP) | VAF 61/277 reads (22%) | called by muse, mutect2, varscan2
